Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0MO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0MO-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: UTERUS AND CERVIX WITH BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY (80 GRAMS) -

- A. WELL-DIFFERENTIATED ENDOMETRIOID ADENOCARCINOMA OF THE ENDOMETRIUM WITH FOCI OF SQUAMOUS DIFFERENTIATION, FIGO GRADE 1 (see comment).
- B. TUMOR MEASURES APPROXIMATELY 2.5 CM IN GREATEST DIMENSION AND OCCUPIES APPROXIMATELY 95% OF BOTH THE ANTERIOR AND POSTERIOR ENDOMETRIUM.
- C. NO LYMPHOVASCULAR INVASION IS IDENTIFIED.
- D. TUMOR INVADES APPROXIMATELY 36% INTO THE ENDOMETRIAL WALL, (0.5 CM INVASION INTO 1.4 CM TOTAL MYOMETRIAL WALL THICKNESS).
- E. CERVIX, NEGATIVE FOR NEOPLASM.
- F. RIGHT AND LEFT FALLOPIAN TUBES WITH PARATUBAL CYSTS, CHRONIC SALPINGITIS, AND REACTIVE CHANGES; NEGATIVE FOR NEOPLASM.
- G. RIGHT AND LEFT OVARIES WITH ENDOSALPINGIOSIS AND BENIGN SURFACE FIBROMAS, NEGATIVE FOR NEOPLASM.

PART 2: RIGHT PELVIC LYMPH NODES, BIOPSY -
THREE LYMPH NODES, NEGATIVE FOR NEOPLASM (0/3).

ICD-0-3

PART 3: RIGHT PELVIC BICIRCUMFLEX LYMPH NODES, BIOPSY -
FIBROADIPOSE TISSUE, NEGATIVE FOR NEOPLASM.

Adenocarcinoma, endometrioid, nos 8380/3

PART 4: RIGHT OBTURATOR LYMPH NODES, BIOPSY -
THREE LYMPH NODES, NEGATIVE FOR NEOPLASM (0/3).

Site: Endometrium C54-1

hw 5/3/11

PART 5: RIGHT COMMON AND PERIAORTIC LYMPH NODES, BIOPSY -
TWO LYMPH NODES, NEGATIVE FOR NEOPLASM (0/2).

PART 6: RIGHT COMMON AND PERIAORTIC LYMPH NODES, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR NEOPLASM (0/1).

PART 7: LEFT PELVIC BICIRCUMFLEX LYMPH NODES, BIOPSY -
THREE LYMPH NODES, NEGATIVE FOR NEOPLASM (0/3).

PART 8: LEFT PELVIC LYMPH NODES, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR NEOPLASM (0/1).

PART 9: LEFT OBTURATOR LYMPH NODES, BIOPSY -
FOUR LYMPH NODES, NEGATIVE FOR NEOPLASM (0/4).

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE:

Adenocarcinoma with squamous metaplasia

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Well differentiated (FIGO 1)

ARCHITECTURAL GRADE:

Well differentiated

NUCLEAR GRADE:

Grade 1

TUMOR SIZE:

Maximum dimension: 2.5 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 95 %, Posterior endomyometrium: 95 %

DEPTH OF INVASION**:

Less than 1/2 thickness of myometrium

MARGINS OF RESECTION:

Vaginal margin is negative for tumor, Parametrium margin is negative for tumor

ANGIOLYMPHATIC INVASION:

No

LYMPH NODES POSITIVE:

Number of lymph nodes positive:: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 17

T STAGE, PATHOLOGIC:

pT1b

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IB

Source: NCI Genomic Data Commons file f9f4314c-6c57-46d9-8f81-10806e996267 (TCGA-BG-A0MO.C120AC98-36D2-49AD-84A1-6EA168D2A2BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).